Surgical pathology report (de-identified scan), TCGA case TCGA-2Y-A9H1, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-2Y-A9H1-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. LIVER, LEFT LATERAL SEGMENT, SEGMENTECTOMY:
Hepatocellular carcinoma, see Key Pathological Findings.

I, _____ the attending pathologist, personally reviewed the entire case and rendered the final diagnosis. Electronically signed out by

Ancillary Studies

Immunohistochemistry stains were performed with adequate controls on block A4 and revealed the tumor cells to be positive for AFP, Hep-par1, CEA-p (canalicular pattern), CK7 and CK20. Special stains Trichrome, reticulin, and iron were performed with adequate controls on block A5 and showed portal fibrosis with short fibrous septa and no excess iron.

Key Pathological Findings

A: Liver, Resection, Synoptic Data

SPECIMEN TYPE: Left lateral segmentectomy

FOCALITY:

Solitary (specify location): left lateral segment

TUMOR SIZE: 3.1 cm

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE: GII: Moderately differentiated

PRIMARY TUMOR (pT): pT1: Solitary tumor with no vascular invasion

REGIONAL LYMPH NODES (pN): pNX: Cannot be assessed

DISTANT METASTASIS (pM): pMX: Cannot be assessed

MARGINS:

Parenchymal margin uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 9 mm

*VENOUS (LARGE VESSEL) INVASION (V): *Absent

*ADDITIONAL PATHOLOGIC FINDINGS:

*Other (specify): fibrous expansion of some portal areas with short fibrous septa (modified Ishak stage 1)

*ICD O3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
J 4/28/14*

Specimen(s) Received

- A LEFT LATERAL SEGMENT OF LIVER FS

Clinical History

LIVER CA
HCC.

Preoperative Diagnosis

Liver cancer, HCC.

Frozen Section Diagnosis

[page 2 of 2]
FSA1. LEFT LATERAL SEGMENT OF LIVER:

Approximately 3.5 cm nodule at least 1 cm from all margins.

Comment: This frozen section diagnosis/result was communicated to and acknowledged by
in at

I, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is received fresh labeled "left lateral segment of liver" and consists of a previously incised, 138 gram, 11.9 x 7.8 x 4.2 cm wedge of liver with numerous staples at the resection margin. The capsule is smooth, purple red with a 2.7 cm subcapsular nodule. Sectioning reveals a 3.1 x 2.6 x 2.2 cm, tan yellow nodule which extends 1.1 cm from the parenchymal margin up to the overlying capsule. The surrounding parenchyma is dense, tan brown and mildly indurated. The parenchymal margin is inked blue, the specimen is serially sectioned and representative sections are submitted as labeled:

A1-A3: Tumor to parenchymal margin
A4-A5: Tumor to adjacent parenchyma and capsule
A7: Vascular margins
A8: Normal-appearing parenchyma

Tissue is submitted to Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 9bb50d35-683b-446c-8fd1-8e0226ec8306 (TCGA-2Y-A9H1.04B342FC-F63A-4C81-BFF7-556C0424BF97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).